Somatic mutation profile of tumor specimen TCGA-CV-A463-01A (aliquot TCGA-CV-A463-01A-11D-A25Y-08) from TCGA case TCGA-CV-A463, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 82.4 years (30,095 days).
Specimen TCGA-CV-A463-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f2a2404-493c-4772-8720-1c9b0247e08b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-A463-10A (Blood Derived Normal), aliquot TCGA-CV-A463-10A-01D-A25Y-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb7f76d8-d878-4948-8355-6ce2714ebcb4

The open-access MAF lists 244 somatic variants for this specimen: 177 protein-altering or splice-affecting, 61 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 150, Silent 61, Nonsense Mutation 24, Intron 3, RNA 2, Frame Shift Del 1, 3'UTR 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.839G>A p.R280K | Missense Mutation (SNP) | VAF 16/60 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- AARS1 | c.203G>A p.R68K | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs750454792, COSV99933239; called by muse, mutect2, varscan2
- ABHD11 | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.19); catalogued as rs369972809; called by muse, mutect2, varscan2
- ABHD8 | c.465G>T p.K155N | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99395442; called by muse, mutect2, varscan2
- ABO | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.658); catalogued as COSV101505935; called by muse, mutect2
- AC100868.1 | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.221); catalogued as rs969270149, COSV51841790, COSV99225412; called by muse, mutect2, varscan2
- ACCSL | c.1698G>C p.M566I | Missense Mutation (SNP) | VAF 81/267 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV101122155; called by muse, mutect2, varscan2
- AFMID | c.707C>T p.T236I | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as rs752166435, COSV100014837; called by muse, mutect2, varscan2
- AHCTF1 | c.5723G>A p.R1908K (on ENST00000366508; = p.R1882K on NM_015446.5) | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs756471351, COSV100403202; called by muse, mutect2, varscan2
- AJUBA | c.1111C>T p.R371* | Nonsense Mutation (SNP) | VAF 20/97 reads (21%) | catalogued as rs768530887, COSV52985232; called by muse, mutect2, varscan2
- AP001781.2 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.01); catalogued as COSV99499532; called by muse, mutect2, varscan2
- ASB18 | c.152A>G p.N51S | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.311); catalogued as COSV101293583; called by muse, mutect2, varscan2
- ATM | c.8260A>G p.T2754A | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.944); catalogued as rs587781414, COSV99587714; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP10B | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 122/194 reads (63%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1044191232, COSV100469129; called by muse, mutect2, varscan2
- ATP8B2 | c.3254G>A p.R1085Q (on ENST00000672630; = p.R1052Q on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0.334); catalogued as rs866091584, COSV59244623; called by muse, mutect2, varscan2
- ATR | c.297C>G p.F99L | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.97); catalogued as COSV100637740, COSV63387192; called by muse, mutect2, varscan2
- ATXN2 | c.3788A>G p.H1263R (on ENST00000550104; = p.H1103R on NM_002973.4) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as COSV100374054; called by muse, mutect2, varscan2
- ATXN7L2 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.971); catalogued as rs1273525493, COSV100149758; called by muse, mutect2, varscan2
- B4GALNT3 | c.2807C>T p.S936F | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99842561; called by muse, mutect2, varscan2
- BBS7 | c.2101G>A p.D701N | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as COSV99144826; called by muse, mutect2, varscan2
- BBS9 | c.550C>T p.L184F | Missense Mutation (SNP) | VAF 56/153 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.723); catalogued as COSV99626345; called by muse, mutect2, varscan2
- BRIP1 | c.2233G>A p.A745T | Missense Mutation (SNP) | VAF 56/216 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs587780235, CM1210625, COSV52004661; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C16orf71 | c.1063G>A p.G355S | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV99556202; called by muse, mutect2, varscan2
- C1orf105 | c.104G>A p.R35K | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs775512356, COSV99278151; called by muse, mutect2, varscan2
- C1orf87 | c.1321T>A p.S441T | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.366); catalogued as COSV100966949; called by muse, mutect2, varscan2
- CASP8 | c.1015C>T p.Q339* (on ENST00000432109 / NM_033355.3; = p.Q356* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 39/139 reads (28%) | catalogued as COSV51852083; called by muse, mutect2, varscan2
- CCDC27 | c.1373G>A p.R458Q | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.66); PolyPhen benign (0.049); catalogued as rs768109329, COSV53899687; called by muse, mutect2, varscan2
- CDC37L1 | c.49G>T p.E17* | Nonsense Mutation (SNP) | VAF 41/65 reads (63%) | catalogued as COSV101116479; called by muse, mutect2, varscan2
- CDR1 | c.537G>A p.W179* | Nonsense Mutation (SNP) | VAF 75/327 reads (23%) | catalogued as COSV100983383; called by muse, mutect2, varscan2
- CES1 | c.1108G>A p.E370K (on ENST00000361503 / NM_001025194.2; = p.E369K on NM_001266.5) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.65); catalogued as rs185780477, COSV100828576; called by muse, mutect2
- CFAP54 | c.6739G>T p.D2247Y | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV100732990, COSV61574379; called by muse, mutect2, varscan2
- CHRNB3 | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV51495439; called by muse, mutect2, varscan2
- CNGB3 | c.2044G>A p.G682S | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.022); catalogued as rs1266563395, COSV100181241; called by muse, mutect2, varscan2
- COL15A1 | c.2066C>T p.S689L | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as COSV100897464; called by muse, mutect2
- CPN1 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 83/286 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.522); catalogued as COSV100962559, COSV64942603; called by muse, mutect2, varscan2
- CPNE3 | c.1162C>T p.Q388* | Nonsense Mutation (SNP) | VAF 33/113 reads (29%) | catalogued as COSV99547219; called by muse, mutect2, varscan2
- CPT2 | c.1177C>T p.Q393* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as COSV99598062; called by muse, mutect2, varscan2
- CRY1 | c.418G>C p.E140Q | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.309); catalogued as COSV99150413; called by muse, mutect2, varscan2
- CSMD2 | c.659C>T p.S220L | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs759006019, COSV53905731; called by muse, mutect2, varscan2
- CTSK | c.275G>C p.G92A | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV99648564; called by muse, mutect2, varscan2
- DCAF11 | c.238G>C p.D80H | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100386593; called by muse, mutect2, varscan2
- DIDO1 | c.6250G>A p.E2084K | Missense Mutation (SNP) | VAF 90/293 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV56623218; called by muse, mutect2, varscan2
- DLG2 | c.553C>T p.R185* | Nonsense Mutation (SNP) | VAF 16/82 reads (20%) | catalogued as COSV54689884; called by muse, mutect2, varscan2
- DMBX1 | c.967T>C p.S323P | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); catalogued as rs1341684197, COSV100760676; called by muse, mutect2, varscan2
- DSC2 | c.887C>G p.S296C | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99199516; called by muse, mutect2, varscan2
- ECHDC2 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.559); catalogued as COSV100597496; called by muse, mutect2, varscan2
- EIF2B4 | c.283C>T p.R95W (on ENST00000347454 / NM_001034116.2; = p.R94W on NM_015636.3) | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs756288383, COSV99277315; called by muse, mutect2, varscan2
- EPG5 | c.7081G>C p.E2361Q | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.329); catalogued as COSV99956613; called by muse, mutect2, varscan2
- ERAP2 | c.1820C>G p.S607* | Nonsense Mutation (SNP) | VAF 44/67 reads (66%) | catalogued as COSV101163520, COSV101163748; called by muse, mutect2, varscan2
- ERP44 | c.1069C>T p.H357Y | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99316198; called by muse, mutect2, varscan2
- FAM47A | c.1257T>G p.S419R | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.013); catalogued as COSV100649756; called by muse, mutect2, varscan2
- FAM47B | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs368344355, COSV61455944, COSV99051670; called by muse, mutect2, varscan2
- FAT1 | c.10118C>G p.S3373* | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | catalogued as COSV71675300; called by muse, mutect2, varscan2
- FAT1 | c.2653C>T p.R885* | Nonsense Mutation (SNP) | VAF 36/136 reads (26%) | catalogued as COSV71673627; called by muse, mutect2, varscan2
- FAT3 | c.9381C>G p.N3127K | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV99962642; called by muse, mutect2, varscan2
- FBXL7 | c.571G>A p.V191I | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.088); catalogued as COSV61643392; called by muse, mutect2
- FBXO40 | c.1279G>C p.A427P | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV100572961; called by muse, mutect2, varscan2
- FBXO44 | c.157C>T p.R53* | Nonsense Mutation (SNP) | VAF 27/125 reads (22%) | catalogued as rs781121590, COSV99278757; called by muse, mutect2, varscan2
- FLG2 | c.1828G>A p.E610K | Missense Mutation (SNP) | VAF 20/335 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.03); catalogued as COSV101165622, COSV66167067; called by muse, mutect2
- FMNL3 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as COSV99525721; called by muse, mutect2, varscan2
- FUT6 | c.695C>A p.T232N | Missense Mutation (SNP) | VAF 45/180 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as rs761907532, COSV99744301; called by muse, mutect2, varscan2
- GDF6 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 78/264 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs1394645319, COSV99747716; called by muse, mutect2, varscan2
- GLMN | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.066); catalogued as COSV64861079; called by muse, varscan2
- GPR156 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100251161; called by muse, mutect2, varscan2
- GRID2 | c.1610C>T p.T537M | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1445827888, COSV56202763; called by muse, mutect2, varscan2
- HACE1 | c.2599C>T p.P867S | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV99493356; called by muse, mutect2, varscan2
- HDAC4 | c.610G>A p.G204R | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs768071233, COSV100612773; called by muse, mutect2, varscan2
- HDX | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV99946646; called by muse, mutect2, varscan2
- HECW2 | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 51/231 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.843); catalogued as rs776152737, COSV53659807; called by muse, mutect2, varscan2
- HIC2 | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); catalogued as rs1373681786, COSV101335544; called by muse, mutect2, varscan2
- HYDIN | c.6202G>T p.D2068Y | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99992121; called by muse, mutect2, varscan2
- IDUA | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99925725; called by muse, mutect2, varscan2
- IGFBP1 | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.794); catalogued as COSV51874550, COSV99298653, COSV99298719; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1877G>A p.R626Q | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.776); catalogued as COSV56239630; called by muse, mutect2, varscan2
- INTS13 | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT tolerated (0.75); PolyPhen benign (0.01); catalogued as COSV99677164; called by muse, mutect2, varscan2
- IPO11 | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV57571863; called by muse, mutect2
- IQGAP1 | c.4314G>A p.M1438I | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.067); catalogued as rs752418699, COSV99184879; called by muse, mutect2, varscan2
- ITIH5 | c.185C>G p.S62C | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99903865; called by muse, mutect2, varscan2
- ITIH6 | c.3243C>A p.D1081E | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV54490227, COSV99512914; called by muse, mutect2, varscan2
- KCNJ8 | c.949G>T p.E317* | Nonsense Mutation (SNP) | VAF 27/97 reads (28%) | catalogued as COSV99557399; called by muse, mutect2, varscan2
- KMT5B | c.2353G>A p.E785K | Missense Mutation (SNP) | VAF 66/241 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV100429955; called by muse, mutect2, varscan2
- MAMDC4 | c.220G>A p.G74S | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763614993, COSV99915480; called by muse, mutect2, varscan2
- MAP1A | c.7G>A p.G3S | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs748004825, COSV100288738, COSV55810982; called by muse, mutect2, varscan2
- MRM3 | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.94); PolyPhen benign (0.005); catalogued as COSV100022451; called by muse, mutect2, varscan2
- MROH9 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV100882706, COSV100882731; called by muse, mutect2, varscan2
- MRPS24 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100451457; called by muse, mutect2, varscan2
- MYCBP2 | c.11741T>C p.M3914T (on ENST00000357337; = p.M3952T on NM_015057.5) | Missense Mutation (SNP) | VAF 45/217 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV62015116; called by muse, mutect2, varscan2
- MYH9 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53381589; called by muse, mutect2, varscan2
- NAGPA | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 60/227 reads (26%) | PolyPhen probably damaging (1); catalogued as rs145897634, COSV100392838; called by muse, mutect2, varscan2
- NAPSA | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1303590192, COSV99515738; called by muse, mutect2, varscan2
- NCCRP1 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs202154753, COSV59212485; called by muse, mutect2, varscan2
- NINJ1 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.188); catalogued as rs781713267, COSV100966602; called by muse, mutect2, varscan2
- NKG7 | c.155C>T p.S52L | Missense Mutation (SNP) | VAF 62/250 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV99389788; called by muse, mutect2, varscan2
- NOTCH1 | c.2798G>T p.C933F | Missense Mutation (SNP) | VAF 29/178 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99485847; called by muse, mutect2, varscan2
- NOTCH1 | c.2038G>A p.D680N | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.123); catalogued as rs749761941, COSV99485851, COSV99491451; called by muse, mutect2, varscan2
- NOTCH1 | c.1823C>G p.S608C | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.617); catalogued as rs558914849, COSV99485852; called by muse, mutect2, varscan2
- NOTCH1 | c.784C>G p.P262A | Missense Mutation (SNP) | VAF 35/197 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.868); catalogued as COSV99485855; called by muse, mutect2, varscan2
- OR4K2 | c.473G>T p.S158I | Missense Mutation (SNP) | VAF 74/386 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as COSV100063916; called by muse, mutect2, varscan2
- OR5C1 | c.70C>G p.R24G | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.127); catalogued as COSV101030526, COSV65455914; called by muse, mutect2, varscan2
- OSBPL6 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99506763; called by muse, mutect2, varscan2
- P4HTM | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100637515; called by muse, mutect2
- PARP14 | c.565G>C p.D189H | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV101506234; called by muse, mutect2, varscan2
- PARP8 | c.1327G>C p.E443Q | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.133); catalogued as COSV99890195; called by muse, mutect2, varscan2
- PCARE | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs192023448, COSV100527355; called by muse, mutect2, varscan2
- PCDH17 | c.1930G>T p.E644* | Nonsense Mutation (SNP) | VAF 43/253 reads (17%) | catalogued as COSV100931462; called by muse, mutect2, varscan2
- PCDHB12 | c.2057T>A p.L686H | Missense Mutation (SNP) | VAF 129/186 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.355); catalogued as COSV99506827; called by muse, mutect2, varscan2
- PDHA2 | c.876G>A p.M292I | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV54777364, COSV99756551; called by muse, mutect2, varscan2
- PHF20 | c.1888C>T p.Q630* | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | catalogued as COSV100179917; called by muse, mutect2, varscan2
- PKHD1L1 | c.1341A>C p.R447S | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.186); catalogued as COSV101005517; called by muse, mutect2
- PLA2G4D | c.1489G>A p.V497I | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs765518884, COSV99299317; called by muse, mutect2, varscan2
- PLCL1 | c.1757C>T p.S586F | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs72556386, COSV101406810; called by muse, mutect2, varscan2
- PNLIPRP3 | c.947C>G p.S316C | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as COSV100982264, COSV100982369; called by muse, mutect2, varscan2
- PRPF3 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 46/188 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as COSV100254555; called by muse, mutect2, varscan2
- PRPF38A | c.934G>T p.E312* | Nonsense Mutation (SNP) | VAF 9/53 reads (17%) | catalogued as COSV99933193; called by muse, mutect2, varscan2
- PRRG3 | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100948558, COSV64851060; called by muse, mutect2, varscan2
- PSME4 | c.1406C>T p.S469L | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.025); catalogued as COSV101122274; called by muse, mutect2, varscan2
- PTPN13 | c.2767C>T p.R923* | Nonsense Mutation (SNP) | VAF 36/132 reads (27%) | catalogued as COSV100364078; called by muse, mutect2, varscan2
- RAB11B | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); catalogued as COSV100032937; called by muse, mutect2
- RAD51AP1 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 63/246 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs373217149; called by muse, varscan2
- RBL1 | c.2270C>T p.S757L | Missense Mutation (SNP) | VAF 61/218 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV100726896; called by muse, mutect2, varscan2
- RBM10 | c.505C>T p.Q169* | Nonsense Mutation (SNP) | VAF 10/69 reads (14%) | catalogued as COSV61310255; called by muse, mutect2, varscan2
- RBM12 | c.2309C>T p.P770L | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as rs750368665, COSV58292688; called by muse, mutect2, varscan2
- REV3L | c.6532G>C p.E2178Q | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.034); catalogued as COSV100724939; called by muse, mutect2, varscan2
- RITA1 | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs781555939, COSV100232277; called by muse, mutect2, varscan2
- RPIA | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs375132883; called by muse, mutect2, varscan2
- RPTN | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 38/347 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as rs1323739061, COSV60166634; called by muse, mutect2, varscan2
- SACS | c.6655C>G p.L2219V | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as rs1443155249, COSV101207220; called by muse, mutect2, varscan2
- SEMA4D | c.2446G>T p.E816* | Nonsense Mutation (SNP) | VAF 16/83 reads (19%) | catalogued as COSV100358001; called by muse, mutect2, varscan2
- SLC13A3 | c.1739C>T p.A580V | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as COSV99286262; called by muse, mutect2, varscan2
- SLC4A7 | c.2389C>G p.L797V | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as COSV55394705, COSV99839273; called by muse, mutect2, varscan2
- SNX19 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); catalogued as COSV99772855; called by muse, mutect2, varscan2
- SORCS1 | c.2432C>A p.A811E | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs150967356, COSV53884334; called by muse, mutect2, varscan2
- SORCS1 | c.2431G>A p.A811T | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.734); catalogued as COSV99543858; called by muse, mutect2, varscan2
- SPEF1 | c.222G>A p.R74= | Splice Region (SNP) | VAF 5/15 reads (33%) | catalogued as COSV101124207; called by muse, mutect2, varscan2
- SPEN | c.5834C>T p.P1945L | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.07); catalogued as COSV101005023; called by muse, mutect2, varscan2
- SPTBN2 | c.6254G>A p.R2085Q | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.91); PolyPhen benign (0.011); catalogued as rs143781509, COSV99047505; called by muse, mutect2, varscan2
- SRARP | c.310G>T p.A104S | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV100272919; called by muse, mutect2, varscan2
- STKLD1 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 69/406 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs782811199, COSV100911908; called by muse, mutect2, varscan2
- STX19 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV57402663; called by muse, mutect2, varscan2
- SULT1A2 | c.683C>T p.S228L | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1232719146, COSV100187046; called by muse, mutect2, varscan2
- TBC1D10A | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.206); catalogued as COSV53166041, COSV53166534; called by muse, mutect2
- TBC1D4 | c.3609G>C p.E1203D | Missense Mutation (SNP) | VAF 43/192 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100884535; called by muse, mutect2, varscan2
- TMEM132D | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 17/75 reads (23%) | catalogued as COSV101396643; called by muse, mutect2, varscan2
- TMEM184A | c.1234G>T p.D412Y | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99867895; called by muse, mutect2
- TMEM35A | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100877436; called by muse, mutect2, varscan2
- TNS1 | c.3878C>T p.A1293V | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV99409970; called by muse, mutect2, varscan2
- TP53BP1 | c.1936G>T p.E646* | Nonsense Mutation (SNP) | VAF 42/145 reads (29%) | catalogued as COSV99779914; called by muse, mutect2, varscan2
- TRBV6-1 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 85/192 reads (44%) | SIFT tolerated (0.62); PolyPhen benign (0.022); catalogued as rs770660010; called by muse, mutect2, varscan2
- TREX2 | c.700G>A p.E234K (on ENST00000334497; = p.E191K on NM_080701.3) | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100444009; called by muse, mutect2
- TRPM3 | c.2168C>T p.A723V (on ENST00000357533 / NM_001366142.2; = p.A566V on NM_020952.6) | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as COSV62585440; called by muse, mutect2, varscan2
- TRPM8 | c.616G>C p.E206Q | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.986); catalogued as COSV100223685; called by muse, mutect2, varscan2
- TTN | c.32302G>A p.E10768K (on ENST00000591111; = p.E9841K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/62 reads (29%) | PolyPhen possibly damaging (0.54); catalogued as rs1472562714, COSV100597426; called by muse, mutect2, varscan2
- UGT1A6 | c.1516T>C p.F506L | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.89); PolyPhen benign (0.363); catalogued as COSV100529698; called by muse, mutect2, varscan2
- UGT2B10 | c.1248C>G p.F416L | Missense Mutation (SNP) | VAF 60/273 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV99607941; called by muse, mutect2, varscan2
- UIMC1 | c.259C>G p.L87V | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101022050; called by muse, mutect2, varscan2
- UNC5B | c.2501G>A p.G834D | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.031); catalogued as COSV100100300; called by muse, mutect2, varscan2
- USF1 | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756601757, COSV99230820; called by muse, mutect2, varscan2
- USP33 | c.1924C>G p.L642V | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV100657030; called by muse, mutect2, varscan2
- USP9X | c.1216C>T p.Q406* | Nonsense Mutation (SNP) | VAF 20/65 reads (31%) | catalogued as COSV100198573, COSV61066468; called by muse, mutect2, varscan2
- VPS13D | c.8514G>A p.W2838* | Nonsense Mutation (SNP) | VAF 33/107 reads (31%) | catalogued as COSV99165581; called by muse, mutect2, varscan2
- WDR59 | c.2794C>T p.R932W | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs762127264, COSV50932997; called by muse, mutect2, varscan2
- YLPM1 | c.4307T>G p.L1436* | Nonsense Mutation (SNP) | VAF 52/170 reads (31%) | catalogued as COSV99458730; called by muse, mutect2, varscan2
- ZFHX4 | c.7267C>G p.Q2423E | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.153); catalogued as COSV99257463; called by muse, mutect2
- ZFX | c.2357G>A p.R786Q | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.153); catalogued as rs748417793, COSV58447078; called by muse, mutect2, varscan2
- ZFYVE16 | c.3815C>T p.S1272F | Missense Mutation (SNP) | VAF 55/86 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100566232; called by muse, mutect2, varscan2
- ZNF264 | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99567122; called by muse, mutect2
- ZNF425 | c.1375G>A p.A459T | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.679); catalogued as rs1301944149, COSV100955400; called by muse, mutect2, varscan2
- ZNF521 | c.949G>C p.E317Q | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100831525; called by muse, mutect2, varscan2
- ZNF562 | c.1157C>T p.T386M (on ENST00000453372 / NM_001130032.2; = p.T314M on NM_017656.4) | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.616); catalogued as rs570871699, COSV53332770; called by muse, mutect2, varscan2
- ZPBP | c.296C>T p.S99L | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV99249160; called by muse, mutect2, varscan2
- ZXDB | c.2219C>T p.S740L | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV66493114; called by muse, mutect2, varscan2
- ANKRD20A1 | c.949G>T p.G317* | Nonsense Mutation (SNP) | VAF 30/259 reads (12%) | called by muse, mutect2, varscan2
- HUWE1 | c.12610_12612del p.K4204del | In Frame Del (DEL) | VAF 22/74 reads (30%) | called by pindel, varscan2
- ICAM4 | c.191C>T p.S64L | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MLLT6 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- SOX5 | c.70G>A p.G24R | Missense Mutation (SNP) | VAF 54/203 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.944); called by muse, mutect2
- TSGA10 | c.675del p.K225Nfs*69 | Frame Shift Del (DEL) | VAF 21/80 reads (26%) | called by mutect2, pindel, varscan2
- ABCA2 | c.6501C>T p.D2167= (on ENST00000614293; = p.D2137= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as rs771335514, COSV99686681; called by muse, mutect2, varscan2
- ADGRG2 | c.3006C>G p.L1002= (on ENST00000379869 / NM_001079858.3; = p.L999= on NM_005756.4) | Silent (SNP) | VAF 39/204 reads (19%) | catalogued as rs762498645, COSV100491937; called by muse, mutect2, varscan2
- ADH1B | c.273C>T p.I91= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV100520655; called by muse, varscan2
- ALOX12 | c.1086G>A p.L362= | Silent (SNP) | VAF 29/154 reads (19%) | catalogued as COSV52348646; called by muse, mutect2, varscan2
- ATP2B2 | c.2775G>A p.L925= (on ENST00000352432; = p.L891= on NM_001683.5) | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as rs144283368, COSV59506194; called by muse, mutect2, varscan2
- ATXN1 | c.987G>A p.E329= | Silent (SNP) | VAF 30/91 reads (33%) | catalogued as COSV99785251; called by muse, mutect2, varscan2
- BCAT2 | c.435G>A p.L145= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV100302304; called by muse, mutect2, varscan2
- BGN | c.546C>T p.L182= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as COSV100525101; called by muse, mutect2, varscan2
- CEL | c.564G>A p.R188= (on ENST00000673714; = p.R185= on NM_001807.6) | Silent (SNP) | VAF 36/175 reads (21%) | catalogued as COSV100672257; called by muse, mutect2, varscan2
- CEL | c.2196T>C p.G732= (on ENST00000673714; = p.G729= on NM_001807.6) | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV100672259; called by muse, mutect2, varscan2
- COL4A6 | c.4359C>T p.P1453= | Silent (SNP) | VAF 36/147 reads (24%) | catalogued as COSV100563485; called by muse, mutect2, varscan2
- CTNNA2 | c.927C>T p.S309= | Silent (SNP) | VAF 29/118 reads (25%) | catalogued as COSV100782018; called by muse, mutect2, varscan2
- DNMBP | c.2151C>G p.L717= | Silent (SNP) | VAF 36/115 reads (31%) | catalogued as COSV100143172; called by muse, mutect2, varscan2
- EPHX4 | c.721C>T p.L241= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV64889435; called by muse, mutect2, varscan2
- FBP2 | c.552C>T p.L184= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as COSV100942081; called by muse, mutect2, varscan2
- FMR1NB | c.243C>T p.F81= | Silent (SNP) | VAF 41/139 reads (29%) | catalogued as COSV65071787; called by muse, mutect2, varscan2
- FRMPD2 | c.3348G>A p.P1116= | Silent (SNP) | VAF 39/177 reads (22%) | catalogued as rs1371179526, COSV100563558; called by muse, mutect2, varscan2
- GJA3 | c.117C>T p.A39= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV99576274; called by muse, mutect2, varscan2
- GJA4 | c.741C>T p.D247= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs368424355; called by muse, mutect2, varscan2
- GPR135 | c.921G>A p.S307= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs1275972505, COSV101229297; called by muse, mutect2, varscan2
- GPR161 | c.1554C>T p.I518= | Silent (SNP) | VAF 25/115 reads (22%) | catalogued as rs757739221, COSV99606296; called by muse, mutect2, varscan2
- IFT52 | c.1218C>T p.I406= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as rs758698679, COSV100887550; called by muse, mutect2, varscan2
- IQSEC3 | c.1902C>T p.C634= (on ENST00000538872 / NM_001170738.2; = p.C331= on NM_015232.1) | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV100406890; called by muse, mutect2
- ITGA2 | c.1902C>T p.T634= | Silent (SNP) | VAF 84/142 reads (59%) | catalogued as rs144430073; called by muse, mutect2, varscan2
- KCNA3 | c.420C>T p.F140= | Silent (SNP) | VAF 29/118 reads (25%) | catalogued as COSV63902349; called by muse, mutect2, varscan2
- KCNJ8 | c.810G>A p.V270= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV99557400; called by muse, mutect2, varscan2
- KIF1C | c.813C>T p.I271= | Silent (SNP) | VAF 22/97 reads (23%) | catalogued as COSV100296983; called by muse, mutect2, varscan2
- KRTAP10-3 | c.594C>G p.L198= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV59962109; called by muse, mutect2, varscan2
- LRPPRC | c.1023C>T p.L341= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as COSV99580011; called by muse, mutect2, varscan2
- MAPK4 | c.1158G>A p.S386= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs762462142, COSV101245183; called by muse, mutect2, varscan2
- MTM1 | c.591T>C p.T197= | Silent (SNP) | VAF 29/135 reads (21%) | catalogued as CD972338, COSV100080217; called by muse, mutect2, varscan2
- MUC5B | c.10416T>G p.T3472= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as COSV101500064; called by muse, varscan2
- NAT9 | c.579C>T p.H193= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as rs781337986, COSV99379830; called by muse, mutect2, varscan2
- NPY5R | c.1224C>T p.C408= | Silent (SNP) | VAF 45/130 reads (35%) | catalogued as COSV58452154; called by muse, mutect2, varscan2
- PACSIN2 | c.1335G>A p.L445= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV54321987, COSV99605949; called by muse, mutect2, varscan2
- PDE11A | c.1242C>T p.A414= | Silent (SNP) | VAF 29/110 reads (26%) | catalogued as COSV53687146, COSV99611043; called by muse, mutect2, varscan2
- PHKA2 | c.2745C>G p.L915= | Silent (SNP) | VAF 37/183 reads (20%) | catalogued as COSV101176741; called by muse, mutect2, varscan2
- PIKFYVE | c.42T>C p.A14= | Silent (SNP) | VAF 71/243 reads (29%) | catalogued as COSV100009974; called by muse, mutect2, varscan2
- PLA2G6 | c.9C>T p.F3= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV100140228, COSV100140242; called by muse, mutect2, varscan2
- PLXNB1 | c.4005C>T p.I1335= | Silent (SNP) | VAF 37/110 reads (34%) | catalogued as COSV99602363; called by muse, mutect2, varscan2
- RAI2 | c.243G>C p.L81= | Silent (SNP) | VAF 59/180 reads (33%) | catalogued as rs770207709, COSV100518176, COSV100518483; called by muse, mutect2, varscan2
- RAP1GAP2 | c.1710G>T p.L570= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV99622499; called by muse, mutect2, varscan2
- RBM25 | c.630T>G p.A210= | Silent (SNP) | VAF 23/97 reads (24%) | catalogued as COSV99998465; called by muse, mutect2, varscan2
- RNF208 | c.474C>T p.R158= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs1451728581, COSV100763111; called by muse, mutect2, varscan2
- RPS6KA4 | c.2085G>A p.G695= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV99589830; called by muse, mutect2, varscan2
- SCO2 | c.540C>T p.Y180= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as rs375795527; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC7A9 | c.639C>T p.G213= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as rs763216072, COSV99195207; ClinVar: uncertain significance; called by muse, mutect2
- SPINK1 | c.123G>A p.K41= | Silent (SNP) | VAF 8/83 reads (10%) | catalogued as rs1425423799, CM1312311, COSV99692826; called by muse, mutect2, varscan2
- STARD5 | c.534C>A p.T178= | Silent (SNP) | VAF 32/102 reads (31%) | catalogued as COSV100250949, COSV57154928; called by muse, mutect2, varscan2
- STXBP5L | c.3078G>A p.R1026= | Silent (SNP) | VAF 33/110 reads (30%) | catalogued as COSV99872367; called by muse, mutect2, varscan2
- SUPT6H | c.1233G>A p.E411= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as COSV100112166; called by muse, mutect2, varscan2
- TEKT4 | c.249G>A p.T83= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs112496617, COSV54628256; called by muse, mutect2, varscan2
- TMED9 | c.642C>T p.L214= | Silent (SNP) | VAF 16/97 reads (16%) | catalogued as rs370667269, COSV50354313; called by muse, mutect2, varscan2
- TMTC2 | c.270C>T p.V90= | Silent (SNP) | VAF 41/137 reads (30%) | catalogued as COSV100337608; called by muse, mutect2, varscan2
- TTLL2 | c.1269G>A p.E423= | Silent (SNP) | VAF 34/112 reads (30%) | catalogued as rs1331105620, COSV99514440; called by muse, mutect2, varscan2
- TUBB6 | c.270C>T p.F90= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs1324251587, COSV100480964; called by muse, mutect2, varscan2
- UNC13C | c.3294C>T p.H1098= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as rs747429185, COSV99512531; called by muse, mutect2, varscan2
- VANGL2 | c.471C>T p.L157= | Silent (SNP) | VAF 24/92 reads (26%) | catalogued as rs777157722, COSV63604326; called by muse, mutect2, varscan2
- ZNF423 | c.2238C>T p.H746= (on ENST00000563137 / NM_001379286.1; = p.H738= on NM_015069.4) | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV99280183; called by muse, mutect2, varscan2
- ZNF536 | c.402C>T p.L134= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV100834789, COSV62820113; called by muse, mutect2, varscan2
- ZNF624 | c.957C>G p.L319= | Silent (SNP) | VAF 28/132 reads (21%) | catalogued as COSV100257051; called by muse, mutect2, varscan2
- CABYR | c.*17-187C>G | Intron (SNP) | VAF 27/96 reads (28%) | catalogued as COSV100111225; called by muse, mutect2, varscan2
- FOLH1B | n.1656G>C | RNA (SNP) | VAF 43/165 reads (26%) | called by muse, mutect2, varscan2
- FRMPD2B | n.557A>G | RNA (SNP) | VAF 44/247 reads (18%) | called by muse, mutect2, varscan2
- IQSEC2 | c.737+12280A>T | Intron (SNP) | VAF 15/45 reads (33%) | catalogued as COSV100944752; called by muse, mutect2, varscan2
- MAF | c.*1G>T | 3'UTR (SNP) | VAF 8/32 reads (25%) | catalogued as COSV100391672; called by muse, mutect2, varscan2
- TBX1 | c.1009+749C>T | Intron (SNP) | VAF 7/18 reads (39%) | catalogued as rs765827356, COSV100226381; called by muse, varscan2
